Somatic mutation profile of tumor specimen MP2PRT-PARPTE-TMP1-A (aliquot MP2PRT-PARPTE-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARPTE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.4 years (2,702 days).
Specimen MP2PRT-PARPTE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 980ea9b6-8bdf-4880-b6fd-9cc3057bc2ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARPTE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARPTE-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/323a4387-a6e4-4ffb-a5f7-dd0c6d0e5dc6

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, Nonsense Mutation 1, Frame Shift Del 1, Frame Shift Ins 1, RNA 1, 5'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF2 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 32/768 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs200490489, COSV99663239; called by muse, mutect2
- DDX3X | c.1217G>T p.R406I (on ENST00000399959; = p.R407I on NM_001356.5) | Missense Mutation (SNP) | VAF 144/416 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV67863498; called by muse, mutect2, varscan2
- FMO3 | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs146765448, COSV63006943; called by muse, mutect2, varscan2
- GPR45 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 267/612 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51523209; called by muse, mutect2, varscan2
- GRM4 | c.1300C>T p.L434F | Missense Mutation (SNP) | VAF 263/665 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs747952325; called by muse, mutect2, varscan2
- HEATR3 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 185/908 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1467109256, COSV53530328; called by muse, mutect2, varscan2
- KSR2 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 83/518 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs375751976, COSV56671133; called by muse, mutect2, varscan2
- OR14I1 | c.745T>G p.F249V | Missense Mutation (SNP) | VAF 62/452 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV61199477; called by muse, mutect2, varscan2
- OR51M1 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 58/440 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs374323334, COSV60783860; called by muse, mutect2, varscan2
- POLR2C | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 27/444 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.474); catalogued as rs749585380, COSV54671709; called by muse, mutect2
- SLC43A3 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 82/471 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150725321; called by muse, mutect2, varscan2
- SLC4A1 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 301/778 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs186542577; called by muse, mutect2, varscan2
- TENM2 | c.2714G>A p.R905H (on ENST00000518659 / NM_001122679.2; = p.R673H on NM_001080428.3) | Missense Mutation (SNP) | VAF 160/390 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs770648894, COSV101319369; called by muse, varscan2
- TRPC1 | c.925C>T p.R309C (on ENST00000476941 / NM_001251845.2; = p.R275C on NM_003304.4) | Missense Mutation (SNP) | VAF 75/183 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56425338; called by muse, mutect2, varscan2
- DOT1L | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 163/402 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGLV4-69 | c.359delinsCCC | In Frame Ins (INS) | VAF 76/166 reads (46%) | called by pindel, varscan2*
- KAT6B | c.5204_5220del p.L1735Qfs*34 | Frame Shift Del (DEL) | VAF 185/562 reads (33%) | called by mutect2, pindel, varscan2
- KMT2D | c.3859dup p.E1287Gfs*38 | Frame Shift Ins (INS) | VAF 241/687 reads (35%) | called by mutect2, pindel, varscan2
- NPAS1 | c.209A>G p.K70R | Missense Mutation (SNP) | VAF 171/841 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- PAX5 | c.576_577insTAGGGC p.A192_D193ins* | Nonsense Mutation (INS) | VAF 142/408 reads (35%) | called by pindel, varscan2
- PAX5 | c.343A>G p.R115G | Missense Mutation (SNP) | VAF 247/618 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SLC45A4 | c.517G>A p.D173N (on ENST00000517878 / NM_001286646.2; = p.D122N on NM_001080431.2) | Missense Mutation (SNP) | VAF 165/682 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZEB2 | c.3215A>G p.Q1072R | Missense Mutation (SNP) | VAF 210/540 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- BROX | c.1044T>C p.Y348= | Silent (SNP) | VAF 169/373 reads (45%) | called by muse, mutect2, varscan2
- MBD5 | c.4458A>G p.K1486= | Silent (SNP) | VAF 57/344 reads (17%) | called by muse, mutect2, varscan2
- SPAST | c.90C>G p.A30= | Silent (SNP) | VAF 349/790 reads (44%) | called by muse, mutect2, varscan2
- SPATA32 | c.763A>C p.R255= | Silent (SNP) | VAF 200/460 reads (43%) | called by muse, mutect2, varscan2
- ZNF722P | c.579G>A p.S193= | Silent (SNP) | VAF 35/247 reads (14%) | catalogued as rs1177121350; called by muse, mutect2, varscan2
- IGHV1-58 | chr14:106627248 ins GGTCGGGGA | 5'Flank (INS) | VAF 104/253 reads (41%) | called by pindel, varscan2
- SLC22A17 | n.1058C>T | RNA (SNP) | VAF 210/477 reads (44%) | catalogued as rs766134891, COSV52835293; called by muse, mutect2, varscan2
